MMRF case MMRF_1659 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f3bd395b-bd40-473a-ae14-b8b3b083f732

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.0 years (18,618 days); ISS stage: III; Days to last known disease status: 1,178 days (3.2 years); Days to last follow up: 1,178 days (3.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 323 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 7 days; Days to treatment end: 323 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 21 days; Days to treatment end: 323 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 331 days; Days to treatment end: 416 days (1.1 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 420 days (1.1 years); Days to treatment end: 463 days (1.3 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 420 days (1.1 years); Days to treatment end: 589 days (1.6 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 505 days (1.4 years); Days to treatment end: 506 days (1.4 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 508 days (1.4 years); Days to treatment end: 508 days (1.4 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 679 days (1.9 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,178.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.559 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4583 mg/dL; Immunoglobulin G 2.36 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 9 µg/mL; Lactate Dehydrogenase 7.48 µkat/L; Hemoglobin 3.66 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 3.5 mmol/L; Albumin 44 g/L; Total Protein 8.4 g/dL; Glucose 7.48 mmol/L.
- Day 98 (ECOG 1): M Protein 0.2 g/dL; Lactate Dehydrogenase 3.97 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.09 mmol/L; Albumin 46 g/L; Total Protein 6.9 g/dL; Glucose 5.45 mmol/L.
- Day 178 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.348 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 306 mg/dL; Immunoglobulin G 2.66 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.37 mmol/L; Albumin 55 g/L; Total Protein 6.7 g/dL; Glucose 5.56 mmol/L.
- Day 281 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.284 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 584 mg/dL; Lactate Dehydrogenase 4 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6 g/dL; Glucose 5.23 mmol/L.
- Day 357 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 774 mg/dL; Immunoglobulin G 1.47 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 5.4 µkat/L; Hemoglobin 4.71 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.24 mmol/L; Albumin 45 g/L; Total Protein 6.3 g/dL; Glucose 6.33 mmol/L.
- Day 438 (ECOG 1): M Protein 0.3 g/dL; Lactate Dehydrogenase 8.22 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 6.16 mmol/L.
- Day 548 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.477 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 348 mg/dL; Immunoglobulin G 2.42 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6 g/dL; Glucose 5.45 mmol/L.
- Day 638 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 156 mg/dL; Immunoglobulin G 3.73 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 3.7 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.43 mmol/L; Albumin 47 g/L; Total Protein 6.6 g/dL; Glucose 5.61 mmol/L.
- Day 721 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.692 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 490 mg/dL; Immunoglobulin G 5.45 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 5.02 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 5.39 mmol/L.
- Day 815 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.779 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 230 mg/dL; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 1.3 ×10⁹/L; Absolute Neutrophil 0.6 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 1.95 mmol/L; Albumin 33 g/L; Total Protein 6.2 g/dL; Glucose 8.25 mmol/L.
- Day 893 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 64.2 mg/dL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.03 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 5.17 mmol/L.
- Day 1,001 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 151 mg/dL; Immunoglobulin G 3.91 g/L; Immunoglobulin A 2 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.1 mmol/L; Albumin 33 g/L; Total Protein 6.5 g/dL; Glucose 5.72 mmol/L.
- Day 1,092 (ECOG 1): Hemoglobin 6.76 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.05 mmol/L; Albumin 30 g/L; Total Protein 5.7 g/dL; Glucose 6.66 mmol/L.
- Day 1,169 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.735 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 133 mg/dL; Lactate Dehydrogenase 4.43 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 7.5 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 1.95 mmol/L; Albumin 28 g/L; Total Protein 5.9 g/dL; Glucose 4.57 mmol/L.

Other clinical attributes
- Day 1: Weight: 81 kg; Height: 182 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Multiple Myeloma; Relationship sex at birth: female.

Biospecimens (4 samples)
- Sample MMRF_1659_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1659_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 98 days.
- Sample MMRF_1659_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 98 days.
- Sample MMRF_1659_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 638 days (1.7 years).
